TCGA case TCGA-EK-A2H1 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/690a7b2a-7dc5-4504-9372-70c8b55e81c7

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 20 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 20.9 years (7,649 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; FIGO stage: Stage IB2; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 799 days (2.2 years).
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Days to treatment start: 70 days; Days to treatment end: 70 days; Number of cycles: 1; Treatment dose: 640 mg; Prescribed dose: 400; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 44 (prior to adjuvant therapy): ECOG performance status: 0.
- Days to follow up: 799 days (2.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 160 cm; BMI: 24.2.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-EK-A2H1-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 2; Percent necrosis: 3; Percent stromal cells: 15; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2H1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Endocervical curettage, cervical cone biopsy; Lymphovascular invasion: Absent.
- Follow-up form: Performance status timing: Pre-Adjuvant Therapy; Radiation adjuvant indicator: Yes; New tumor event diagnosis indicator: No.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 799 days; disease-specific survival: no event (censored), 799 days; progression-free interval: no event (censored), 799 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2H1-01A-11D-A17U-01): tumor purity 0.42, ploidy 2.16, whole-genome doublings 0.
